Gene-level copy-number profile of tumor specimen TCGA-AF-3913-01A from TCGA case TCGA-AF-3913, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.2 years (21,970 days).
Specimen TCGA-AF-3913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.d68b4100-30e4-4124-8267-cf58d023e666.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-3913-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d21bd11-9f6c-4172-a1b9-4cad4e32fe5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 3,522; copy number 2: 34,976; copy number 3: 11,693; copy number 4: 3,552; copy number 5: 5,159; copy number 6: 653; copy number 7: 12; copy number 8: 234.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AF-3913-01): tumor purity 0.76, ploidy 2.51, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–7,126,639, 8 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,058 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (broad region; genes not listed).
- chr8:65,155,407–84,142,463, 285 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:111,376,639–111,757,710, 1 gene, copy number 5 (within-gene range 3–5): LINC02237.
- chr8:111,621,458–115,809,673, 17 genes, copy number 5: H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1.
- chr8:142,111,414–145,066,685, 168 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 5 (broad region; genes not listed).
- chr12:114,353,911–115,886,137, 28 genes, copy number 5 (within-gene range 3–5): TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3.
- chr12:115,961,187–116,082,676, 2 genes, copy number 5: AC012157.2, RNU6-1188P.
- chr13:18,467,172–84,902,424, 988 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:29,038,655–32,003,728, 234 genes, copy number 8 (broad region; genes not listed).
- chr19:27,638,483–28,727,777, 26 genes, copy number 5–7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1.
- chr20:36,996,349–60,083,872, 519 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,520. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
